Somatic mutation profile of tumor specimen TCGA-IS-A3KA-01A (aliquot TCGA-IS-A3KA-01A-11D-A21Q-09) from TCGA case TCGA-IS-A3KA, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 73.3 years (26,775 days).
Specimen TCGA-IS-A3KA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fea4495-dde4-4d99-abd2-515ea24616d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IS-A3KA-10A (Blood Derived Normal), aliquot TCGA-IS-A3KA-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34e6b4f9-c278-45bc-b88f-7b5211bc6275

The open-access MAF lists 63 somatic variants for this specimen: 49 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 12, Nonsense Mutation 3, Splice Site 3, RNA 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 19/23 reads (83%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKFN1 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.511); catalogued as rs749177645, COSV59442660; called by muse, mutect2, varscan2
- ARHGEF15 | c.1421+1G>T p.X474_splice | Splice Site (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100729973; called by muse, mutect2, varscan2
- BRINP1 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.964); catalogued as rs746081030, COSV56297318; called by muse, mutect2, varscan2
- CDH18 | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99934842; called by muse, mutect2, varscan2
- CEP131 | c.1061C>A p.A354E | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.287); catalogued as COSV99487804; called by muse, mutect2
- FCHO1 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs781383645, COSV53182478, COSV53184078; called by muse, mutect2, varscan2
- FDXACB1 | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs137921139; called by muse, mutect2, varscan2
- GCM2 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs536827295; called by muse, mutect2, varscan2
- HSPA12B | c.937+1G>C p.X313_splice | Splice Site (SNP) | VAF 24/91 reads (26%) | catalogued as COSV99421951; called by muse, mutect2, varscan2
- KIF20A | c.2491G>A p.G831S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.212); catalogued as rs1440426128; called by muse, mutect2
- LGMN | c.403A>T p.S135C | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100605694; called by muse, mutect2, varscan2
- NPTN | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1010733301, COSV54737442; called by muse, mutect2, varscan2
- PKP2 | c.1839C>A p.N613K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM085058; called by muse, mutect2, varscan2
- PLCE1 | c.3103G>T p.G1035* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99593418; called by mutect2, varscan2
- PTK2 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs191376716; called by muse, mutect2, varscan2
- RIT2 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs754435765, COSV56308980; called by muse, mutect2, varscan2
- RUNDC3B | c.317G>A p.S106N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.665); catalogued as rs139503670; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2576G>A p.R859Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs376885416; called by muse, mutect2, varscan2
- TMEM217 | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 441/476 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100362481; called by muse, mutect2, varscan2
- TMEM217 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 184/205 reads (90%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); catalogued as COSV100362495; called by muse, mutect2, varscan2
- WNK3 | c.3997C>A p.Q1333K | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV63615520; called by muse, mutect2, varscan2
- ZNF462 | c.5243C>T p.P1748L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); catalogued as rs773727987, COSV52931634; called by muse, mutect2, varscan2
- ZNHIT2 | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs757807935; called by muse, varscan2
- ZSWIM8 | c.2372G>T p.R791L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.153); catalogued as rs747757512; called by muse, mutect2, varscan2
- ACAN | c.2917C>T p.L973F | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ALS2CL | c.2421T>A p.D807E | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- APEX2 | c.1416C>A p.H472Q | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ATG2A | c.1331C>G p.P444R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- CYP4Z1 | c.1504A>T p.K502* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- DMPK | c.1263G>C p.M421I | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DOP1B | c.3315C>G p.D1105E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FOLH1B | n.988-1G>T | Splice Site (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
- IDUA | c.804C>A p.S268R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- IQGAP3 | c.3377C>T p.T1126I | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA2026 | c.6178A>T p.T2060S | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- KIAA2026 | c.2207A>G p.K736R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- LONRF3 | c.1405C>G p.L469V (on ENST00000371628 / NM_001031855.3; = p.L428V on NM_024778.5) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- NUTM1 | c.2882C>G p.P961R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLXNB1 | c.1685_1691dup p.G565Vfs*32 | Frame Shift Ins (INS) | VAF 18/84 reads (21%) | called by mutect2, varscan2
- RB1 | c.1321del p.I441Lfs*16 | Frame Shift Del (DEL) | VAF 15/31 reads (48%) | called by mutect2, pindel, varscan2
- SERPIND1 | c.965A>T p.K322M | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- SSX2IP | c.1682T>C p.V561A | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAB2 | c.7418G>C p.G2473A | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TONSL | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- TSKS | c.1287G>C p.Q429H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- UBA1 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- ZNF451 | c.2863G>A p.D955N (on ENST00000370706 / NM_001031623.3; = p.D907N on NM_015555.2) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF804B | c.1355A>G p.H452R | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- HBD | c.18T>G p.P6= | Silent (SNP) | VAF 11/131 reads (8%) | called by muse, mutect2
- MMP27 | c.225T>C p.T75= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs768266547; called by muse, mutect2, varscan2
- OR13D1 | c.240C>A p.I80= | Silent (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.1110C>T p.D370= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs774990344, COSV53920308; called by muse, mutect2, varscan2
- PIKFYVE | c.5595C>A p.A1865= | Silent (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- PLCB2 | c.711G>A p.T237= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as rs777100325; called by muse, mutect2
- RS1 | c.621C>T p.H207= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as rs281865360, CM981771; called by muse, mutect2, varscan2
- SLC25A48 | c.372G>T p.V124= | Silent (SNP) | VAF 19/86 reads (22%) | called by muse, mutect2, varscan2
- SREBF2 | c.1821A>G p.A607= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs753747422; called by muse, mutect2, varscan2
- TLL1 | c.444C>A p.A148= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs147468832, COSV50276269; called by muse, mutect2, varscan2
- XRCC3 | c.886C>T p.L296= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- ZNF451 | c.2805G>A p.L935= (on ENST00000370706 / NM_001031623.3; = p.L887= on NM_015555.2) | Silent (SNP) | VAF 17/97 reads (18%) | called by muse, varscan2
- DCHS2 | n.6003C>T | RNA (SNP) | VAF 7/34 reads (21%) | catalogued as rs1370868285, COSV61769507; called by muse, mutect2, varscan2
- METTL16 | n.1104C>T | RNA (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
